Somatic mutation profile of tumor specimen TCGA-DU-5852-01A (aliquot TCGA-DU-5852-01A-11D-1705-08) from TCGA case TCGA-DU-5852, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 61.2 years (22,348 days).
Specimen TCGA-DU-5852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba127ee7-e935-444b-a886-ba43e11ebc57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5852-10A (Blood Derived Normal), aliquot TCGA-DU-5852-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d3fbe85-ad4f-420a-a26a-3be17601439f

The open-access MAF lists 80 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Nonsense Mutation 3, RNA 2, In Frame Del 1, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 44/199 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2, varscan2
- F8 | c.6976C>T p.R2326* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs137852354, CM850004, CM990566, COSV57704724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as COSV54952783; called by muse, mutect2, varscan2
- ALPK3 | c.2537del p.G846Efs*12 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as COSV51934219; called by mutect2, pindel, varscan2
- ATRX | c.7252T>A p.Y2418N | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100970172; called by mutect2, varscan2
- AUTS2 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV61392065; called by muse, mutect2, varscan2
- BRD2 | c.2026T>A p.L676I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66372901; called by muse, mutect2, varscan2
- C10orf71 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.095); catalogued as COSV60506210; called by muse, mutect2, varscan2
- CACNA1F | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59903760; called by muse, mutect2, varscan2
- CDH13 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs867465333, COSV51805503; called by muse, mutect2, varscan2
- CEMIP | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751210792, COSV54990091; called by muse, mutect2, varscan2
- COL17A1 | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62226124; called by muse, mutect2, varscan2
- CUL1 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57387752; called by mutect2, varscan2
- DCAF4L2 | c.1000C>G p.Q334E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60477561; called by muse, mutect2, varscan2
- DPPA3 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV61502890; called by muse, mutect2, varscan2
- F5 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs535939475, COSV63122450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM83G | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs776432523, COSV58756642; called by muse, mutect2, varscan2
- GAB2 | c.1813C>T p.P605S (on ENST00000361507 / NM_080491.3; = p.P567S on NM_012296.3) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.162); catalogued as COSV60866933; called by muse, mutect2, varscan2
- HACE1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs761336527, COSV53501253, COSV99494043; called by muse, mutect2, varscan2
- HRH1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as rs139664451; called by muse, mutect2, varscan2
- HTR3A | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs1404509414, COSV55468678; called by muse, mutect2, varscan2
- KLK1 | c.548A>C p.D183A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV56826417; called by muse, mutect2, varscan2
- LAMA3 | c.2372A>T p.Y791F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.929); catalogued as COSV58066030; called by muse, mutect2, varscan2
- LRRC4B | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.173); catalogued as rs770871502, COSV65349620; called by muse, mutect2, varscan2
- MYOCD | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs531377746, COSV58500836; called by muse, mutect2, varscan2
- NDUFAF7 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as rs764261689, COSV50017147; called by muse, mutect2, varscan2
- NUDT7 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs370570737; called by muse, mutect2, varscan2
- OR14C36 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs145207343, COSV58602779; called by muse, mutect2, varscan2
- OR2T3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1384054805, COSV100613104; called by muse, mutect2, varscan2
- OR51A4 | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV66749255; called by muse, mutect2, varscan2
- OR6M1 | c.804C>G p.D268E | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV58433159; called by muse, mutect2, varscan2
- PACSIN1 | c.1037+1G>A p.X346_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV55059316; called by muse, mutect2, varscan2
- PAX8 | c.192G>T p.R64S | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs560233979, COSV54507484; called by mutect2, varscan2
- PBRM1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56269026; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDHA8 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100970487; called by mutect2, varscan2
- PLCG1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54815150; called by muse, mutect2, varscan2
- POLR2G | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.496); catalogued as COSV57135026; called by muse, mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- PROKR2 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370738961, CM1010043; called by muse, mutect2, varscan2
- RANGRF | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs200615633, COSV56839195; called by muse, mutect2, varscan2
- RET | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.753); catalogued as rs529018971, COSV60690418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SECISBP2 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); catalogued as COSV60527998; called by muse, mutect2, varscan2
- SLAMF7 | c.378G>A p.E126= | Splice Region (SNP) | VAF 57/155 reads (37%) | catalogued as rs1364368414, COSV63562987; called by muse, mutect2, varscan2
- SLC35F1 | c.1140A>C p.L380F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.317); catalogued as COSV64501341; called by muse, mutect2, varscan2
- SLC35F3 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.722); catalogued as rs146928346; called by muse, mutect2, varscan2
- SLC9A6 | c.1526G>C p.G509A | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV65787691; called by muse, mutect2, varscan2
- SLCO3A1 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs199572762, COSV59227576; called by muse, mutect2, varscan2
- SREBF1 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1391914768, COSV55415699; called by muse, mutect2, varscan2
- SRSF11 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV63938466; called by muse, mutect2, varscan2
- STAG3 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57928884; called by muse, mutect2, varscan2
- STAT6 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs757430778, COSV55670098; called by muse, mutect2, varscan2
- TGIF2LX | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as COSV52213635; called by muse, mutect2, varscan2
- TTC3 | c.3248T>G p.L1083R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV61288385; called by muse, mutect2, varscan2
- USE1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); catalogued as COSV55727436; called by muse, mutect2, varscan2
- YME1L1 | c.1340G>T p.R447I (on ENST00000326799 / NM_139312.3; = p.R390I on NM_014263.4) | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58758664; called by muse, mutect2, varscan2
- AIM2 | c.1010_1012del p.I337del | In Frame Del (DEL) | VAF 16/62 reads (26%) | called by pindel, varscan2
- ELK1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- ABCA4 | c.4947C>T p.P1649= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as rs763852420, CD971957, COSV64672505; called by muse, mutect2, varscan2
- ACE2 | c.2367A>G p.G789= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV53024270; called by muse, mutect2, varscan2
- BTK | c.987G>T p.G329= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV58118436; called by muse, mutect2, varscan2
- DPP3 | c.2112C>T p.F704= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100567718, COSV59148792; called by muse, mutect2, varscan2
- EPG5 | c.3411C>T p.P1137= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56347417; called by muse, mutect2, varscan2
- FAM47C | c.1428G>A p.P476= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1439099049, COSV63724050; called by muse, mutect2, varscan2
- FILIP1 | c.924G>A p.S308= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as rs1310170700, COSV52726253; called by muse, mutect2, varscan2
- GDF3 | c.336C>T p.N112= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV61712090; called by muse, mutect2, varscan2
- GPRASP1 | c.633A>G p.A211= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as COSV64355201; called by muse, mutect2
- KLK15 | c.315C>T p.N105= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs369380000, COSV56826422; called by muse, mutect2, varscan2
- LAMA3 | c.2373C>T p.Y791= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs371550637, COSV100557414; called by muse, mutect2, varscan2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs369104625; called by muse, mutect2, varscan2
- LILRA2 | c.714G>A p.E238= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs144206436, COSV52189985; called by muse, mutect2, varscan2
- MUC5B | c.10587C>T p.T3529= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV71591049; called by muse, mutect2, varscan2
- OVCA2 | c.528G>A p.G176= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV53984100, COSV99559725; called by muse, mutect2, varscan2
- SLC12A3 | c.2547C>T p.L849= (on ENST00000563236 / NM_001126108.2; = p.L858= on NM_000339.3) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs759556270, COSV52633538; called by muse, mutect2, varscan2
- SLC45A4 | c.849C>T p.F283= (on ENST00000517878 / NM_001286646.2; = p.F232= on NM_001080431.2) | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV50135179; called by muse, mutect2, varscan2
- SPANXN1 | c.108C>T p.P36= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs782331742, COSV100979327, COSV65122143; called by muse, mutect2, varscan2
- UBL7 | c.141T>C p.I47= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV63705809; called by muse, mutect2
- USP34 | c.6762G>A p.S2254= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs756433334, COSV68399817; called by muse, mutect2, varscan2
- HERC2P3 | n.2206C>T | RNA (SNP) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- KLRA1P | n.617G>A | RNA (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
